Gene-level copy-number profile of tumor specimen TCGA-04-1519-01A from TCGA case TCGA-04-1519, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.4 years (17,671 days).
Specimen TCGA-04-1519-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.74c4f7e9-6f7e-41b7-8f57-f4cd0a5312d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1519-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ca02a8e9-49fe-46c8-b9e0-1f3356413e30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 20,747; copy number 2: 37,701; copy number 3: 1,093; copy number 4: 115; copy number 5: 164.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1519-01): tumor purity 0.99, ploidy 1.72, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 164 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:14,514,769–16,324,514, 100 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:1,368,977–3,173,592, 64 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,298. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
